Somatic mutation profile of tumor specimen TCGA-D7-A6ET-01A (aliquot TCGA-D7-A6ET-01A-32D-A32N-08) from TCGA case TCGA-D7-A6ET, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 76.5 years (27,928 days).
Specimen TCGA-D7-A6ET-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d648db3-b3f4-4f0d-9dc7-7920afeeca5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-A6ET-10A (Blood Derived Normal), aliquot TCGA-D7-A6ET-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76d20ba1-e460-4567-844f-4fc4db481838

The open-access MAF lists 21 somatic variants for this specimen: 11 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 9, Missense Mutation 9, Nonsense Mutation 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADSS1 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290246650, COSV58274020; called by muse, mutect2
- BCOR | c.1612C>T p.Q538* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100653124; called by muse, mutect2, varscan2
- KCNB2 | c.1798A>T p.T600S | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.475); catalogued as COSV101578723; called by muse, mutect2
- KCNK18 | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100572018; called by muse, mutect2, varscan2
- MTERF2 | c.397A>C p.I133L | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99526745; called by muse, mutect2
- NFATC2 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1272354225, COSV65357238; called by muse, mutect2
- PAGE3 | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV100891979; called by muse, mutect2
- POMGNT1 | c.1462C>T p.R488* | Nonsense Mutation (SNP) | VAF 14/108 reads (13%) | catalogued as rs727504103, COSV64341024; called by muse, mutect2, varscan2
- SAMD7 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV59419189, COSV59422447; called by muse, mutect2
- SYT3 | c.614G>C p.G205A | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV58897328; called by muse, mutect2
- TPGS2 | c.424A>T p.S142C | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV100528803; called by muse, mutect2
- ATP13A1 | c.552G>A p.L184= | Silent (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
- CHST9 | c.30C>A p.P10= | Silent (SNP) | VAF 9/186 reads (5%) | catalogued as COSV99409946; called by muse, mutect2
- CRYGA | c.498T>A p.S166= | Silent (SNP) | VAF 15/219 reads (7%) | catalogued as COSV100378362; called by muse, mutect2
- EXPH5 | c.750C>T p.N250= | Silent (SNP) | VAF 17/166 reads (10%) | catalogued as rs1313874149, COSV99761343; called by muse, mutect2, varscan2
- HLA-C | c.729G>A p.R243= | Silent (SNP) | VAF 8/159 reads (5%) | catalogued as rs1391446040, COSV100880388; called by muse, mutect2
- MASP1 | c.1686A>G p.P562= | Silent (SNP) | VAF 18/226 reads (8%) | catalogued as rs745974441, COSV100537118; called by muse, mutect2
- TBC1D25 | c.1884G>A p.E628= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV100952128; called by muse, mutect2
- TRIM9 | c.1059C>T p.I353= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV100031053; called by muse, mutect2
- ZBED9 | c.1482C>T p.H494= | Silent (SNP) | VAF 9/199 reads (5%) | catalogued as COSV101509200; called by muse, mutect2
- TAOK2 | chr16:29990787 C>T | 3'Flank (SNP) | VAF 10/168 reads (6%) | catalogued as COSV54229225; called by muse, mutect2
